Somatic mutation profile of tumor specimen SM-JU353 (aliquot 7316UP-8) from CPTAC case C247230, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G4.
Specimen SM-JU353: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4dde257f-1158-420f-93cc-c1387dd43af8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105280 (Blood Derived Normal), aliquot 7316UP-243-1105280; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97838ef3-d1b4-472b-bed2-faeaeacac9ce

The open-access MAF lists 61 somatic variants for this specimen: 36 protein-altering or splice-affecting, 16 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 16, Intron 5, Nonsense Mutation 2, Splice Region 1, 5'Flank 1, Frame Shift Del 1, 3'Flank 1, In Frame Del 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC4 | c.2704T>C p.S902P | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1004189967; called by muse, mutect2
- ANKDD1B | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.123); catalogued as rs542617542, COSV72645528; called by muse, mutect2
- CACNA2D4 | c.2587C>T p.R863C | Missense Mutation (SNP) | VAF 135/403 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs775588255; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC6 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 62/96 reads (65%) | SIFT tolerated (0.3); PolyPhen benign (0.338); catalogued as COSV54055823; called by muse, mutect2, varscan2
- CHGB | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.744); catalogued as rs373817587, COSV100972942; called by muse, mutect2, varscan2
- CYP2C18 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 121/206 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767161951; called by muse, mutect2, varscan2
- DNAH12 | c.2950G>A p.A984T (on ENST00000351747; = p.A1007T on NM_001366028.2) | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.841); catalogued as COSV61063067; called by muse, mutect2, varscan2
- GBA | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 125/374 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as rs748485792, CM140309, COSV59169558; called by muse, mutect2, varscan2
- GGT6 | c.526G>A p.G176S (on ENST00000574154 / NM_001122890.3; = p.G144S on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/311 reads (16%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs777856032; called by muse, mutect2, varscan2
- GPATCH8 | c.3095G>A p.R1032H | Missense Mutation (SNP) | VAF 48/293 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs141324123; called by muse, mutect2, varscan2
- IGHM | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 120/302 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs772304630; called by muse, mutect2, varscan2
- LAD1 | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs370468944; called by muse, mutect2, varscan2
- LCE3A | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 62/385 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.006); catalogued as rs547378092, COSV59550310; called by muse, mutect2, varscan2
- MRPL10 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as rs368049321; called by muse, mutect2, varscan2
- RYR1 | c.6445G>A p.V2149M | Missense Mutation (SNP) | VAF 158/565 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs776830747, COSV62109696; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMSN1 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 9/206 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.397); catalogued as rs1453069450; called by muse, mutect2
- SUDS3 | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 21/219 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as COSV64349096; called by muse, mutect2, varscan2
- VPS13D | c.3943C>T p.R1315* | Nonsense Mutation (SNP) | VAF 68/190 reads (36%) | catalogued as rs1014084562, COSV50691564; called by muse, mutect2, varscan2
- WDR64 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.301); catalogued as rs1302850245, COSV63793738, COSV63796103; called by muse, mutect2, varscan2
- ZNF461 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs1356093352, COSV64453450; called by muse, mutect2, varscan2
- ZSWIM4 | c.2035C>T p.R679W | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1007165557; called by muse, mutect2, varscan2
- CHD7 | c.3799G>C p.E1267Q | Missense Mutation (SNP) | VAF 80/193 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CNTNAP5 | c.314G>T p.S105I | Missense Mutation (SNP) | VAF 56/300 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- DNAJC11 | c.1323+5G>T | Splice Region (SNP) | VAF 39/87 reads (45%) | called by muse, mutect2, varscan2
- EGFR | c.554G>A p.G185D | Missense Mutation (SNP) | VAF 92/835 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EQTN | c.224C>G p.P75R | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, varscan2
- FAM71E2 | c.585T>G p.H195Q | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.084); called by muse, varscan2
- GIGYF2 | c.2326G>T p.E776* | Nonsense Mutation (SNP) | VAF 122/325 reads (38%) | called by muse, mutect2, varscan2
- LCP1 | c.1437_1439del p.G480del | In Frame Del (DEL) | VAF 65/303 reads (21%) | called by mutect2, pindel, varscan2
- LIPE | c.1468G>A p.V490M | Missense Mutation (SNP) | VAF 89/298 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- MLLT3 | c.295C>G p.R99G | Missense Mutation (SNP) | VAF 80/211 reads (38%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MYO1H | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 69/205 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCOA2 | c.2693G>C p.G898A | Missense Mutation (SNP) | VAF 139/415 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRELID2 | c.541G>C p.E181Q (on ENST00000334744 / NM_182960.4; = p.E140Q on NM_138492.6) | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- PTEN | c.55del p.D19Mfs*5 | Frame Shift Del (DEL) | VAF 158/338 reads (47%) | called by mutect2, pindel, varscan2
- SLC25A52 | c.409C>T p.L137F (on ENST00000672005; = p.L127F on NM_001034172.4) | Missense Mutation (SNP) | VAF 109/291 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- ADGRG4 | c.5910C>T p.D1970= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as rs760543724, COSV54949082; called by muse, mutect2, varscan2
- ANK1 | c.1866G>A p.L622= | Silent (SNP) | VAF 171/533 reads (32%) | catalogued as rs776247811; called by muse, mutect2, varscan2
- ANKMY2 | c.1266C>T p.S422= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as rs771684492, COSV61011359; called by muse, mutect2, varscan2
- ANKS4B | c.84G>A p.S28= | Silent (SNP) | VAF 59/201 reads (29%) | catalogued as rs376343890; called by muse, mutect2, varscan2
- ARSH | c.321C>T p.G107= | Silent (SNP) | VAF 68/93 reads (73%) | called by muse, mutect2, varscan2
- ASXL1 | c.1830C>T p.G610= | Silent (SNP) | VAF 142/427 reads (33%) | catalogued as rs199829982; called by muse, mutect2, varscan2
- DAW1 | c.1197C>T p.G399= | Silent (SNP) | VAF 49/125 reads (39%) | called by muse, mutect2, varscan2
- KRT19 | c.723G>A p.P241= | Silent (SNP) | VAF 74/272 reads (27%) | catalogued as rs140667731; called by muse, mutect2, varscan2
- OR10R2 | c.783C>T p.C261= | Silent (SNP) | VAF 50/121 reads (41%) | catalogued as rs753353295, COSV63769299, COSV63769398; called by muse, mutect2, varscan2
- OR2T10 | c.313C>T p.L105= | Silent (SNP) | VAF 91/278 reads (33%) | catalogued as COSV57897015, COSV57897073; called by muse, mutect2, varscan2
- OXSR1 | c.264G>A p.L88= | Silent (SNP) | VAF 78/250 reads (31%) | catalogued as COSV61259203; called by muse, mutect2, varscan2
- PCDHGB3 | c.1869G>A p.T623= | Silent (SNP) | VAF 48/322 reads (15%) | catalogued as COSV53937747; called by muse, mutect2, varscan2
- PLCG2 | c.2409C>T p.P803= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as rs774918375; called by muse, mutect2, varscan2
- SLC27A2 | c.831C>T p.H277= | Silent (SNP) | VAF 59/159 reads (37%) | catalogued as rs79765607; called by muse, mutect2, varscan2
- TMEM147 | c.481C>T p.L161= | Silent (SNP) | VAF 88/318 reads (28%) | called by muse, mutect2, varscan2
- USH2A | c.14073C>T p.N4691= | Silent (SNP) | VAF 78/198 reads (39%) | catalogued as rs370364142, COSV56342993; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ACADVL | c.*51G>C | 3'UTR (SNP) | VAF 75/221 reads (34%) | called by muse, mutect2, varscan2
- ANKRD18A | chr9:38621264 G>C | 5'Flank (SNP) | VAF 122/344 reads (35%) | catalogued as rs1457530152; called by muse, mutect2, varscan2
- CEACAM16 | c.-52G>A | 5'UTR (SNP) | VAF 53/263 reads (20%) | catalogued as rs892672015; called by muse, mutect2, varscan2
- LGI4 | c.1300-233C>T | Intron (SNP) | VAF 29/73 reads (40%) | called by muse, mutect2, varscan2
- NADSYN1 | c.146+9A>G | Intron (SNP) | VAF 35/97 reads (36%) | called by muse, mutect2, varscan2
- PAFAH1B2 | chr11:117174909 C>G | 3'Flank (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- PCLO | c.13655-1671G>T | Intron (SNP) | VAF 17/81 reads (21%) | called by muse, mutect2, varscan2
- PNPLA7 | c.1151-3595G>C | Intron (SNP) | VAF 34/112 reads (30%) | called by muse, varscan2
- XKR6 | c.764+92162G>A | Intron (SNP) | VAF 16/74 reads (22%) | catalogued as rs547523766; called by muse, mutect2
